Gene-level copy-number profile of tumor specimen HCM-CSHL-1264-C25-01A from HCMI case HCM-CSHL-1264-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Intraductal papillary-mucinous carcinoma, invasive; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.5 years (28,315 days).
Specimen HCM-CSHL-1264-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 36ba7014-1e06-4763-a4cb-f53781c5da69.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1264-C25-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/d0f804fb-1781-4cf8-b069-608574bf0c66

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 10,494; copy number 2: 43,401; copy number 3: 3,263; copy number 4: 435; copy number 5: 631; copy number 6: 387; copy number 7: 168; copy number 8: 76; copy number 9: 35; copy number 10: 21.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:47,237,734–47,279,021, 3 genes: AC008083.2, AC008083.3, AC008083.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,318 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–151,771,334, 409 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:153,012,482–155,750,137, 167 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:157,232,231–163,355,764, 230 genes, copy number 5–8 (broad region; genes not listed).
- chr1:167,721,192–169,132,722, 36 genes, copy number 6 (within-gene range 4–6): MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1.
- chr1:170,145,959–170,168,866, 1 gene, copy number 5 (within-gene range 4–5): METTL11B.
- chr1:170,173,865–172,418,466, 47 genes, copy number 5–6 (within-gene range 2–6): LINC01681, ISCUP1, LINC01142, HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1.
- chr1:174,110,268–175,012,027, 13 genes, copy number 7 (within-gene range 2–7): RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP.
- chr1:175,877,343–176,447,919, 13 genes, copy number 7: LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7.
- chr1:176,857,302–177,282,422, 3 genes, copy number 6: ASTN1, MIR488, BRINP2.
- chr1:185,558,371–186,988,981, 18 genes, copy number 7: LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, PTGS2, PACERR, PLA2G4A.
- chr1:199,148,598–199,393,307, 3 genes, copy number 5: LINC02789, RPL23AP16, AC099335.1.
- chr1:208,972,454–209,652,425, 15 genes, copy number 6: LINC01774, AC104465.1, AC092810.2, AC092810.1, TFDP1P1, ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2, CAMK1G, LAMB3, MIR4260.
- chr1:215,622,891–216,423,448, 1 gene, copy number 6 (within-gene range 2–6): USH2A.
- chr1:215,886,582–217,137,755, 5 genes, copy number 6: AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG.
- chr1:217,631,324–219,273,387, 23 genes, copy number 5 (within-gene range 5–7): SPATA17, SPATA17-AS1, UBBP2, LINC00210, AL355526.1, LINC01653, AL355526.2, RNU1-141P, RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3, NXNP1, LINC01710, LYPLAL1-DT, LYPLAL1, RIMKLBP2, AL360093.1, AC096642.1.
- chr1:219,685,427–220,360,183, 19 genes, copy number 5: SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1.
- chr1:225,401,502–230,802,003, 170 genes, copy number 5 (broad region; genes not listed).
- chr1:231,018,958–236,921,278, 127 genes, copy number 5–10 (broad region; genes not listed).
- chr8:38,699,274–39,730,065, 18 genes, copy number 6: AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18.

Autosomal genes at a single copy (total copy number 1): 7,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
